Surgical pathology report (de-identified scan), TCGA case TCGA-IS-A3K7, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-IS-A3K7-01A (Primary Tumor).

Specimens Submitted:

- 1: SP: Uterus, cervix, bilat. tubes ovary (fs)
- 2: SP: Posterior bladder wall (fs) (
- 3: SP: Lt. posterior bladder wall (fs) (
- 4: SP: Bladder dome (fs) (

DIAGNOSIS:

- 1) UTERUS, CERVIX, BILATERAL TUBES AND OVARIES; RESECTION:
- LEIOMYOSARCOMA, HIGH GRADE, 10 CM INVOLVING ANTERIOR
UTERINE WALL. VASCULAR INVASION NOTED. UTERINE SEROSAL
SURFACE IS NOT INVOLVED BY TUMOR. ATROPHIC ENDOMETRIUM.
LEFT OVARY WITH BENIGN SEROUS CYST (2 CM). LEFT TUBE WITH
BENIGN PARATUBAL CYST. BENIGN RIGHT OVARY AND TUBE.
- 2) BLADDER, POSTERIOR WALL; BIOPSY:
- BENIGN SMOOTH MUSCLE.
- 3) BLADDER, LEFT POSTERIOR WALL; BIOPSY:
- BENIGN SMOOTH MUSCLE.
- 4) BLADDER, DOME; BIOPSY:
- BENIGN FIBROADIPOSE TISSUE.

ICD-0-3

leiomyosarcoma, NOS 8890/3

Site: uterus, NOS C55.9

hw 12/20/11

** Report Electronically Signed Out **

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION
OF THE SLIDES (AND/OR OTHER
MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Source: NCI Genomic Data Commons file de84cd78-5e29-48b6-b674-2cd62892a43c (TCGA-IS-A3K7.981BD108-4BE8-40A2-8CCE-1250B1296309.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).